Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3592, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3592-01A (Primary Tumor).

Diagnosis/ diagnoses:

Rectosigmoid colon with an ulcerated rectal carcinoma characterized histologically as a moderately differentiated colorectal adenoma, extending at most to within 4 cm of the aboral resection margin, with a diameter of 3 cm at the widest point. Invasive tumor spread to the periproctical fatty tissue. The minimum distance from the soft tissue resection margin is 2 cm. Mucosa of both the rectum and colon shows a tubular adenoma of the colon mucosa, with moderate epithelial dysplasia (synonym: mild intraepithelial neoplasia). In addition, the mucosa of the colon and rectum show pseudomelanosis.

Oral and aboral resection margins tumor-free.

32 periproctical and mesocolic lymph nodes tumor-free and with non-characteristic reactive lesions.

Tumor stage therefore pT3, pN0, (0/32) L0 V0; G2

Source: NCI Genomic Data Commons file dd96026c-1e79-4081-a5b7-6dd529ba1ec2 (TCGA-AG-3592.A4D6676D-ECCB-4334-BDAA-AD532954EEC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).